Somatic mutation profile of tumor specimen TCGA-EE-A29C-06A (aliquot TCGA-EE-A29C-06A-21D-A197-08) from TCGA case TCGA-EE-A29C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 21.4 years (7,810 days).
Specimen TCGA-EE-A29C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7a2aebc-0296-4613-bb63-964362399082.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29C-10A (Blood Derived Normal), aliquot TCGA-EE-A29C-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc70573-b278-4d57-a62f-8314faecdda7

The open-access MAF lists 492 somatic variants for this specimen: 328 protein-altering or splice-affecting, 154 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 154, Nonsense Mutation 14, Splice Site 6, RNA 5, Splice Region 5, Intron 2, Translation Start Site 1, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CLCN1 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746125212, CM950272, COSV58367156; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCND3 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs867628133, COSV56187716; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV66066199; called by muse, mutect2, varscan2
- ABCA8 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV52209687; called by muse, mutect2, varscan2
- ABCB10 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as rs575887540, COSV60622818; called by muse, varscan2
- ABI3BP | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52548201; called by muse, mutect2, varscan2
- ACSF2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV51973568, COSV51973902; called by muse, mutect2, varscan2
- ACSM2B | c.535A>T p.I179F | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs746992275, COSV61659562; called by muse, mutect2, varscan2
- ADAM22 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs757786454, COSV55987238; called by muse, mutect2, varscan2
- ADAM23 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.348); catalogued as rs924943482, COSV52226816; called by muse, mutect2, varscan2
- ADAMTS2 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as rs766947359, COSV52389023; called by muse, mutect2, varscan2
- ADCY1 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1457337652, COSV52040747; called by muse, mutect2, varscan2
- ADRA1A | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52372140; called by muse, mutect2, varscan2
- AKAP1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs267604964, COSV58472331; called by muse, mutect2, varscan2
- ALDOB | c.540G>A p.Q180= | Splice Region (SNP) | VAF 15/56 reads (27%) | catalogued as COSV66398462; called by muse, mutect2, varscan2
- AMBRA1 | c.2632+1G>A p.X878_splice (on ENST00000458649 / NM_001367468.1; = p.X788_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100094179; called by muse, mutect2, varscan2
- AMBRA1 | c.2632G>A p.A878T (on ENST00000458649 / NM_001367468.1; = p.A788T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100094183; called by muse, mutect2, varscan2
- AMFR | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746062824, COSV51923716; called by muse, mutect2, varscan2
- ANK3 | c.10012G>A p.E3338K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV55074567; called by muse, mutect2, varscan2
- AP002512.3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs772474039, COSV54406603; called by muse, mutect2, varscan2
- AP1M1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52225074; called by muse, mutect2, varscan2
- APBA1 | c.1846C>T p.L616F | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55235288; called by muse, mutect2, varscan2
- ARFGEF2 | c.1129G>C p.V377L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as COSV64214518; called by muse, mutect2, varscan2
- ARIH2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62706022, COSV62706572; called by muse, mutect2, varscan2
- ASPM | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV54136574; called by muse, mutect2, varscan2
- ATF6 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100909248; called by muse, mutect2, varscan2
- ATG2A | c.3359C>T p.S1120F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65968458; called by muse, mutect2, varscan2
- ATG9B | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65059344; called by muse, mutect2, varscan2
- ATP10B | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1475604035, COSV58780720; called by muse, mutect2
- ATP13A1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52290366; called by muse, mutect2, varscan2
- ATXN1 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1307206321, COSV55228065; called by muse, mutect2, varscan2
- BMI1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV64958923; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BRCA2 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs1566224075, COSV66460558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6920C>T p.S2307L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV66460567; called by muse, mutect2, varscan2
- BRINP1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs760905731, COSV56310472; called by muse, mutect2, varscan2
- BTN1A1 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV55069175; called by muse, mutect2, varscan2
- C10orf71 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV60511468; called by muse, mutect2, varscan2
- C2CD3 | c.5378C>T p.P1793L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs767013666, COSV58093650; called by muse, mutect2, varscan2
- C4orf50 | c.-4113G>A | Splice Region (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99289756; called by muse, mutect2, varscan2
- C8B | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.927); catalogued as COSV64779135; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2, varscan2
- CCNB3 | c.2446C>T p.L816F | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV52078552; called by muse, mutect2, varscan2
- CCR4 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV58383484; called by muse, mutect2, varscan2
- CD300LB | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV58725844, COSV58726264; called by muse, mutect2, varscan2
- CD300LF | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100042786, COSV56898666; called by muse, mutect2, varscan2
- CDH10 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52593683; called by muse, mutect2
- CDH6 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54076479; called by muse, mutect2, varscan2
- CDK13 | c.2528T>A p.I843N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51705354; called by muse, mutect2, varscan2
- CELF1 | c.946G>A p.G316R (on ENST00000358597 / NM_001376422.1; = p.G312R on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60114849; called by muse, mutect2, varscan2
- CFAP54 | c.7129G>A p.E2377K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV61574618; called by muse, mutect2, varscan2
- CFTR | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV50047277, COSV50086381; called by muse, mutect2, varscan2
- CHAT | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562560467, COSV100340238, COSV60330420; called by muse, mutect2, varscan2
- CHAT | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100340240; called by muse, mutect2, varscan2
- CHSY1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs759168955, COSV54255476; called by muse, mutect2, varscan2
- CILP2 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867787011, COSV52279315; called by muse, mutect2, varscan2
- CLCN1 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380726444, CM1313404, COSV100578107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMTR2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV57604655; called by muse, mutect2, varscan2
- COL1A1 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV56808645; called by muse, mutect2, varscan2
- COL21A1 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769722166, COSV55163893, COSV99778638; called by muse, mutect2, varscan2
- COL4A5 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as COSV60358590; called by muse, mutect2, varscan2
- COPE | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368880349; called by muse, mutect2, varscan2
- COQ9 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV52647085; called by muse, mutect2, varscan2
- CRP | c.62-1G>A p.X21_splice | Splice Site (SNP) | VAF 36/107 reads (34%) | catalogued as COSV99660417, COSV99660609; called by muse, varscan2
- CRTAM | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV57070855; called by muse, mutect2, varscan2
- CSMD2 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs972030736, COSV53950724; called by muse, mutect2, varscan2
- CTTNBP2 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV50455996; called by muse, mutect2, varscan2
- CUL9 | c.3352C>T p.L1118F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52733093; called by muse, mutect2, varscan2
- CYC1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010431; called by muse, mutect2, varscan2
- CYP11B2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763034354, COSV59997453; called by muse, mutect2, varscan2
- CYP21A2 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); catalogued as rs891233264, COSV100926387; called by muse, mutect2, varscan2
- CYP21A2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100926388; called by muse, mutect2, varscan2
- CYP2E1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53314901, COSV99429068; called by muse, mutect2, varscan2
- CYP4A11 | c.1379A>T p.K460I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1171626952, COSV60225167; called by muse, mutect2, varscan2
- DCHS1 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs1433781981, COSV55041141; called by muse, mutect2, varscan2
- DCN | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.228); catalogued as rs770718112, COSV50008815; called by muse, mutect2, varscan2
- DDC | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD045699, COSV63567222; called by muse, mutect2, varscan2
- DENND2C | c.2393G>A p.R798Q (on ENST00000393274 / NM_001256404.2; = p.R741Q on NM_198459.4) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768969571, COSV67922853; called by muse, mutect2, varscan2
- DGKI | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99934945; called by muse, mutect2, varscan2
- DGKI | c.1269A>T p.K423N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934948; called by muse, mutect2, varscan2
- DHTKD1 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 113/528 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99536538; called by muse, mutect2, varscan2
- DHTKD1 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 114/532 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as COSV53801935, COSV53804852; called by muse, mutect2, varscan2
- DNA2 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64429822; called by muse, mutect2, varscan2
- DNAH10 | c.5488G>A p.E1830K (on ENST00000409039; = p.E1769K on NM_207437.3) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV68999619; called by muse, mutect2, varscan2
- DNAH17 | c.5777A>T p.K1926M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67759851; called by muse, mutect2, varscan2
- DNAH3 | c.4988C>T p.P1663L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV54544709; called by muse, mutect2, varscan2
- DNAH5 | c.6491C>T p.T2164I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54246315; called by mutect2, varscan2
- DNAH5 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs372594127; called by muse, mutect2, varscan2
- DNAH9 | c.6295C>T p.P2099S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs149674795; called by muse, mutect2, varscan2
- DNAJC12 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV56549549; called by muse, mutect2, varscan2
- DOP1A | c.5415+1G>A p.X1805_splice | Splice Site (SNP) | VAF 23/90 reads (26%) | catalogued as COSV52716045; called by muse, mutect2, varscan2
- DSG1 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.841); catalogued as COSV57133438; called by muse, varscan2
- DSP | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs371234425; ClinVar: uncertain significance; called by muse, varscan2
- DST | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs1182407897, COSV56841822; called by muse, mutect2, varscan2
- DYSF | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50535066; called by muse, mutect2, varscan2
- DYTN | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV101510845; called by muse, mutect2
- ENPP1 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62935365; called by muse, mutect2, varscan2
- EPB41L1 | c.874-1G>A p.X292_splice | Splice Site (SNP) | VAF 48/179 reads (27%) | catalogued as COSV52442987; called by muse, mutect2, varscan2
- ERCC6 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.395); catalogued as COSV63393536; called by muse, mutect2, varscan2
- ERN2 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 37/119 reads (31%) | catalogued as rs540505898, COSV56831767, COSV99892130; called by muse, mutect2, varscan2
- ESRP2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV52175499, COSV52176591; called by muse, mutect2, varscan2
- FAM131C | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs370377410; called by muse, mutect2, varscan2
- FAM71B | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57230351; called by muse, mutect2, varscan2
- FAR2 | c.566T>G p.I189S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV51728867; called by muse, mutect2, varscan2
- FBN1 | c.2950G>A p.V984I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.959); catalogued as rs747713929, CM960628, COSV100353780, COSV57319967; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FMNL2 | c.1850A>G p.K617R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1254247966, COSV56502469; called by muse, mutect2, varscan2
- FMO2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs145420492, COSV52947781; called by muse, mutect2, varscan2
- FNDC7 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54757029; called by muse, mutect2, varscan2
- FOXP4 | c.767C>T p.A256V (on ENST00000307972 / NM_001012426.1; = p.A255V on NM_138457.3) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs866835572, COSV57223081; called by muse, mutect2, varscan2
- FZD2 | c.1614G>C p.W538C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59529971; called by muse, mutect2, varscan2
- GALK2 | c.1095C>G p.N365K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV59104518; called by muse, mutect2, varscan2
- GALNT17 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.836); catalogued as COSV61184701; called by muse, mutect2, varscan2
- GKAP1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64487492; called by muse, mutect2, varscan2
- GP1BA | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567647832, COSV56700585; called by muse, mutect2
- GRIK4 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV70806095; called by muse, mutect2, varscan2
- GRM3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.155); catalogued as COSV64471988; called by muse, mutect2, varscan2
- GUCY1A2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.119); catalogued as COSV56485399; called by muse, mutect2, varscan2
- HBD | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HCN1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV57532206; called by muse, mutect2
- HEATR1 | c.3947C>T p.P1316L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935904378, COSV63981939, COSV63982401; called by muse, mutect2, varscan2
- HGF | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55947254; called by muse, mutect2, varscan2
- HNF4A | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 153/517 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV57388031; called by muse, mutect2, varscan2
- HTR3B | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52744773; called by muse, mutect2, varscan2
- HUWE1 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV53360511, COSV99470730; called by muse, mutect2, varscan2
- IDO2 | c.892G>A p.D298N (on ENST00000389060; = p.D311N on NM_194294.2) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV58423833; called by muse, mutect2, varscan2
- IDO2 | c.1213C>T p.P405S (on ENST00000389060; = p.P418S on NM_194294.2) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV58428358; called by muse, mutect2, varscan2
- INPP5A | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.069); catalogued as COSV61252283; called by muse, mutect2, varscan2
- INSL5 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV58787880, COSV58788539; called by muse, mutect2, varscan2
- INVS | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52444774, COSV52448143, COSV99317700; called by muse, mutect2, varscan2
- IP6K3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as COSV53390034; called by muse, mutect2, varscan2
- ITGA2 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV56865364; called by muse, mutect2, varscan2
- ITGAX | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51650187; called by muse, mutect2, varscan2
- KCNB2 | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV73052392; called by muse, mutect2, varscan2
- KCNB2 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.662); catalogued as rs767711810, COSV73052394; called by muse, mutect2, varscan2
- KCNG3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60150716; called by muse, mutect2, varscan2
- KCNMA1 | c.3319G>A p.D1107N (on ENST00000286628 / NM_001161352.2; = p.D1049N on NM_002247.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1314238418, COSV54278061; called by muse, mutect2, varscan2
- KCNQ3 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs781473829, COSV66479687; called by muse, mutect2, varscan2
- KEL | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765373517, COSV62336503; called by muse, mutect2, varscan2
- KIAA1755 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs745937778, COSV54077247, COSV99641875; called by muse, mutect2, varscan2
- KLHL4 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV64146813; called by muse, mutect2, varscan2
- KMT2B | c.5725C>T p.P1909S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs769851153, COSV55867385; called by muse, mutect2, varscan2
- KPNA2 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as rs1225490130, COSV57858696; called by muse, mutect2, varscan2
- KRTAP10-9 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 111/337 reads (33%) | catalogued as COSV59975686; called by muse, mutect2, varscan2
- KTN1 | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs759587990, COSV68024215; called by muse, mutect2, varscan2
- LAMA3 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58077156; called by muse, mutect2, varscan2
- LCE1E | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.918); catalogued as COSV64220000; called by muse, varscan2
- LEMD2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs762314184, COSV53393134; called by muse, mutect2, varscan2
- LINGO4 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920536389, COSV63216082; called by muse, varscan2
- LLGL2 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs963325779, COSV51392802; called by muse, mutect2, varscan2
- LRP1 | c.5664C>T p.G1888= | Splice Region (SNP) | VAF 28/99 reads (28%) | catalogued as rs774831075, COSV54522357; called by muse, mutect2, varscan2
- LRP1B | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV67262494, COSV67266284; called by muse, mutect2, varscan2
- LRRC30 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1427287788, COSV67302175; called by muse, mutect2, varscan2
- LUZP2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs150458536, COSV61201811; called by muse, mutect2, varscan2
- MAGEA6 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs782174313, COSV61449359; called by muse, mutect2, varscan2
- MAGEC1 | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752999850, COSV53571509, COSV53574727; called by muse, mutect2, varscan2
- MAPK8IP2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV50507163; called by muse, mutect2, varscan2
- MED12L | c.6329C>T p.T2110I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV56393199; called by muse, mutect2, varscan2
- MGAM | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV72075410; called by muse, mutect2, varscan2
- MGAT3 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs768099655, COSV100361912; called by muse, varscan2
- MGAT3 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs776173478, COSV57866606; called by muse, mutect2, varscan2
- MLKL | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV58206018; called by muse, mutect2, varscan2
- MOGAT3 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56176570; called by muse, mutect2, varscan2
- MPP7 | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145704516; called by muse, varscan2
- MTSS1 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as rs1185350088, COSV61499412; called by muse, mutect2
- MUC16 | c.32530C>T p.H10844Y | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV67486895; called by muse, mutect2, varscan2
- MUC16 | c.25849C>T p.P8617S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV67486901; called by muse, mutect2, varscan2
- MUC16 | c.6440C>T p.P2147L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV67486907; called by muse, mutect2, varscan2
- MUC16 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs779487752, COSV67486912; called by muse, mutect2, varscan2
- MUC17 | c.13192G>A p.G4398R | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV60300164; called by muse, mutect2, varscan2
- MUC4 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.301); catalogued as COSV62152095; called by muse, mutect2, varscan2
- MYH4 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV55115570, COSV55120002; called by muse, mutect2, varscan2
- MYMK | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV60601405; called by muse, mutect2, varscan2
- MYO1G | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777006572, COSV51856560; called by muse, mutect2, varscan2
- N4BP2L2 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs750280447, COSV57229109; called by muse, mutect2, varscan2
- NAALAD2 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58965081; called by muse, mutect2, varscan2
- NAPRT | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52788216; called by muse, mutect2, varscan2
- NCAM2 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV53086413; called by muse, mutect2, varscan2
- NCAM2 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53097425; called by muse, mutect2, varscan2
- NEK10 | c.3050G>A p.G1017E | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55363710; called by muse, mutect2, varscan2
- NGLY1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375732599, COSV54985371, COSV54985691; called by muse, mutect2, varscan2
- NHS | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs761199327, COSV66280773; called by muse, mutect2, varscan2
- NLRP1 | c.2441A>G p.D814G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52575765; called by muse, mutect2, varscan2
- NLRP13 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.059); catalogued as rs370553797; called by muse, mutect2, varscan2
- NMNAT3 | c.139T>G p.S47A (on ENST00000296202 / NM_001320512.1; = p.S10A on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56158838; called by muse, mutect2, varscan2
- NOS1AP | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV62639112; called by muse, mutect2, varscan2
- NOS2 | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58226679; called by muse, mutect2, varscan2
- NPAP1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.163); catalogued as COSV61510350; called by muse, mutect2, varscan2
- NPNT | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs1201780005, COSV59756392; called by muse, mutect2, varscan2
- NR0B2 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 58/82 reads (71%) | catalogued as rs765872687, COSV54260096; called by muse, mutect2, varscan2
- NRG1 | c.1124C>T p.S375F (on ENST00000405005 / NM_013964.5; = p.S380F on NM_013956.5) | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV55172726; called by muse, mutect2, varscan2
- NRG3 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV64579566; called by muse, mutect2, varscan2
- NRXN1 | c.4001G>A p.R1334K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60497722; called by muse, mutect2, varscan2
- NRXN3 | c.1786G>A p.V596M (on ENST00000557594 / NM_001272020.2; = p.V1020M on NM_004796.6) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376483450; called by muse, mutect2, varscan2
- NUCKS1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV63347869; called by muse, mutect2, varscan2
- NUP107 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57497421; called by muse, mutect2, varscan2
- OR10A3 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs146552050; called by muse, mutect2, varscan2
- OR11A1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65821263; called by muse, mutect2, varscan2
- OR13C3 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV66166191; called by muse, mutect2, varscan2
- OR1L6 | c.160C>T p.L54F (on ENST00000373684; = p.L18F on NM_001004453.2) | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV59029494; called by muse, mutect2, varscan2
- OR52A5 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs143161168; called by muse, mutect2, varscan2
- OR52I2 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100442931, COSV57044140; called by muse, mutect2, varscan2
- OR5H15 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62948855; called by muse, mutect2, varscan2
- OR5K3 | c.922T>A p.F308I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV67350554; called by muse, mutect2, varscan2
- OR6C65 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV65568900; called by muse, mutect2, varscan2
- PADI2 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV64945886, COSV64946488; called by muse, mutect2, varscan2
- PAX3 | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99286614; called by muse, mutect2, varscan2
- PCDH15 | c.2549C>A p.A850E | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as COSV57376133; called by muse, mutect2, varscan2
- PCDH15 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs1004800410, COSV57261983, COSV57315868; called by muse, mutect2, varscan2
- PCDHB15 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV51306204; called by muse, mutect2, varscan2
- PCDHB4 | c.1268C>A p.T423N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV52025950; called by muse, mutect2, varscan2
- PCDHGA3 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV54008825; called by muse, mutect2, varscan2
- PCSK7 | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99639062; called by muse, mutect2, varscan2
- PCSK7 | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99639063; called by muse, mutect2, varscan2
- PDE4DIP | c.4166C>T p.S1389L | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs782066972, COSV57671565; called by muse, varscan2
- PHAX | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV52552215; called by muse, mutect2, varscan2
- PHF24 | c.738G>C p.E246D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV54276363; called by muse, mutect2
- PHLDB2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV67313583; called by muse, mutect2, varscan2
- PIK3CB | c.1745G>A p.W582* | Nonsense Mutation (SNP) | VAF 123/460 reads (27%) | catalogued as COSV56689195; called by muse, mutect2, varscan2
- PITPNM2 | c.2278C>T p.H760Y | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV54906930; called by muse, mutect2, varscan2
- PLA2G4D | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV51822978; called by muse, mutect2, varscan2
- PLCH1 | c.3217A>G p.N1073D (on ENST00000340059 / NM_001130960.2; = p.N1065D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58208063; called by muse, mutect2, varscan2
- PLCL1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1249939618, COSV70822087; called by muse, mutect2, varscan2
- PNMA5 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs1398116219, COSV62625908; called by muse, mutect2, varscan2
- PORCN | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58227010; called by muse, mutect2, varscan2
- PRICKLE1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58209788; called by muse, mutect2, varscan2
- PRKDC | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV50630526; called by muse, mutect2, varscan2
- PRPH2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV57838339; called by muse, mutect2, varscan2
- PRR23B | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as rs564951138, COSV100272101; called by muse, mutect2, varscan2
- PRR23B | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs1559938537, COSV61493188; called by muse, mutect2, varscan2
- PRSS1 | c.478T>C p.C160R | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172272446, COSV61196464; called by muse, mutect2
- PRTG | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.998); catalogued as rs750688796, COSV66837159; called by muse, mutect2, varscan2
- PSD | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs557064437, COSV50055373; called by muse, mutect2, varscan2
- PXDNL | c.3383C>T p.S1128F | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV62496436; called by muse, mutect2, varscan2
- PXN | c.1175G>A p.G392E (on ENST00000228307 / NM_001080855.3; = p.G358E on NM_002859.4) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57221214; called by muse, mutect2, varscan2
- RABL6 | c.1541G>A p.R514K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as rs376189168; called by muse, mutect2
- RAG2 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs139419162, COSV57556829; called by muse, varscan2
- RALGAPA2 | c.1928T>A p.I643N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV52508184; called by muse, mutect2, varscan2
- RANBP3L | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV56957281, COSV56958486; called by muse, mutect2, varscan2
- RBM42 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs747322642, COSV99387050; called by muse, mutect2, varscan2
- RECQL5 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV58645330; called by muse, mutect2, varscan2
- RHOH | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67807461; called by muse, mutect2, varscan2
- RHOU | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV64208977; called by muse, mutect2, varscan2
- RIOK1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs200730332, COSV53573311; called by muse, mutect2, varscan2
- RNF139 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.017); catalogued as COSV52681578; called by muse, mutect2, varscan2
- ROBO2 | c.3161A>T p.K1054I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV59933325; called by muse, mutect2, varscan2
- ROS1 | c.2814G>A p.G938= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as COSV63851428; called by muse, mutect2
- RRBP1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV55706561; called by muse, mutect2, varscan2
- RSAD2 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257149634, COSV65908822; called by muse, mutect2, varscan2
- RSPH6A | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV55574550; called by muse, mutect2, varscan2
- RTTN | c.5908T>C p.S1970P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV55350466; called by muse, mutect2, varscan2
- RUNX1T1 | c.1253C>T p.P418L (on ENST00000265814 / NM_001198628.1; = p.P391L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV56146683, COSV56160007; called by muse, mutect2, varscan2
- RUSC2 | c.4345C>T p.P1449S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.203); catalogued as COSV63429988; called by muse, mutect2, varscan2
- RYR1 | c.5408C>T p.P1803L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs778017724, COSV100615530, COSV62107525; called by muse, mutect2, varscan2
- RYR3 | c.10184G>A p.R3395Q (on ENST00000389232; = p.R3396Q on NM_001036.6) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771747010, COSV66777075; called by muse, mutect2, varscan2
- SAMSN1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53476293; called by muse, mutect2, varscan2
- SARS2 | c.1160+1G>A p.X387_splice | Splice Site (SNP) | VAF 22/96 reads (23%) | catalogued as COSV55501256; called by muse, varscan2
- SCN11A | c.4745C>T p.S1582F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs150988853, COSV56576383; called by muse, mutect2, varscan2
- SCNN1G | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55599067; called by muse, mutect2, varscan2
- SEMA3A | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as CM152481, COSV54884790; called by muse, mutect2, varscan2
- SEMA4A | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV61773727; called by muse, mutect2, varscan2
- SEPTIN8 | c.139A>C p.I47L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.31); catalogued as COSV51524897; called by muse, mutect2, varscan2
- SGSH | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV58340231; called by muse, mutect2, varscan2
- SH3BP5L | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100821937, COSV63539765; called by muse, mutect2, varscan2
- SHANK2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV53614801; called by muse, mutect2, varscan2
- SI | c.5015A>T p.Q1672L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52295944; called by muse, mutect2, varscan2
- SLA2 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53412201; called by muse, varscan2
- SLC12A6 | c.3352G>A p.D1118N (on ENST00000354181 / NM_001365088.1; = p.D1067N on NM_005135.2) | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV51630376; called by muse, mutect2, varscan2
- SLC13A3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51721725; called by muse, mutect2, varscan2
- SLC17A7 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV55549662; called by muse, mutect2, varscan2
- SLC24A3 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60122610, COSV60122854; called by muse, mutect2, varscan2
- SLC44A2 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59838528; called by muse, mutect2, varscan2
- SOX10 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV100704137; called by muse, mutect2, varscan2
- SOX10 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV100704139; called by muse, mutect2, varscan2
- SSR2 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55304731; called by muse, mutect2, varscan2
- STAU2 | c.1373C>T p.S458L (on ENST00000524300 / NM_001164380.2; = p.S426L on NM_014393.2) | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1470177363, COSV63306991; called by muse, mutect2, varscan2
- STBD1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs769162728, COSV52954361; called by muse, mutect2, varscan2
- STK11 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 60/142 reads (42%) | catalogued as CM075023, COSV58820688; called by muse, mutect2, varscan2
- STON1 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746203027, COSV59136327; called by muse, varscan2
- TAOK1 | c.306+2T>C p.X102_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55597289; called by muse, mutect2
- TAOK2 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99663094; called by muse, mutect2, varscan2
- TBX4 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53606311, COSV99540756; called by muse, mutect2, varscan2
- TBX5 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV59864434; called by muse, mutect2, varscan2
- TEAD2 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755358183, COSV60545099; called by muse, mutect2, varscan2
- TENT2 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1436965549, COSV99706570; called by muse, mutect2, varscan2
- TET2 | c.3281A>T p.K1094I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54427995; called by muse, mutect2, varscan2
- THEMIS | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs750429003, COSV64073692; called by muse, mutect2, varscan2
- TMC5 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1207690251, COSV66868216; called by muse, mutect2, varscan2
- TMEM119 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as rs1298630779, COSV67189255; called by muse, mutect2, varscan2
- TMEM30A | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100034942, COSV57876668; called by muse, mutect2, varscan2
- TNRC6C | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs780312107, COSV56951565; called by muse, varscan2
- TOX2 | c.1054C>T p.P352S (on ENST00000358131 / NM_001098798.2; = p.P328S on NM_032883.3) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV57893599; called by muse, mutect2, varscan2
- TPO | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61109105; called by muse, mutect2, varscan2
- TRPM2 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV55975412; called by muse, mutect2, varscan2
- TSPAN32 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs866426833, COSV51721543; called by muse, mutect2, varscan2
- TTN | c.29266A>T p.I9756F (on ENST00000591111; = p.I8829F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/193 reads (9%) | PolyPhen possibly damaging (0.899); catalogued as COSV60279224; called by muse, mutect2
- UBR5 | c.3324C>T p.A1108= | Splice Region (SNP) | VAF 11/44 reads (25%) | catalogued as COSV55296904; called by muse, mutect2, varscan2
- UBR5 | c.1492C>G p.P498A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55296915; called by muse, mutect2, varscan2
- ULBP1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.212); catalogued as rs1554270011, COSV57664897; called by muse, mutect2
- USH2A | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV56420506; called by muse, mutect2, varscan2
- USP31 | c.3962C>T p.P1321L | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs376807590; called by muse, mutect2, varscan2
- VPS13D | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV62533448; called by muse, mutect2, varscan2
- VPS29 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62195379; called by muse, mutect2, varscan2
- VPS8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as COSV54994392; called by muse, mutect2, varscan2
- VWF | c.6563G>A p.G2188E | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99779222; called by muse, mutect2, varscan2
- VWF | c.6562G>C p.G2188R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54631970, COSV99779225; called by muse, mutect2, varscan2
- WDR46 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466504209; called by mutect2, varscan2
- WDR53 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV60284840; called by muse, mutect2, varscan2
- WIZ | c.3920T>A p.M1307K (on ENST00000673675 / NM_001371589.1; = p.M212K on NM_021241.3) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV54611399; called by muse, mutect2, varscan2
- WNK2 | c.6704C>T p.P2235L (on ENST00000297954 / NM_001282394.1; = p.P2198L on NM_006648.3) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1247542757, COSV52956703; called by muse, mutect2, varscan2
- WSCD2 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1220023701, COSV54589392; called by muse, mutect2, varscan2
- ZBED9 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs542386571, COSV71729709; called by muse, mutect2
- ZBTB38 | c.3488A>T p.H1163L | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58543757; called by muse, mutect2, varscan2
- ZFAND2A | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV57180970; called by muse, mutect2, varscan2
- ZFHX3 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213006; called by muse, mutect2, varscan2
- ZFYVE9 | c.3641G>A p.G1214E | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55098482; called by muse, mutect2, varscan2
- ZNF12 | c.631C>T p.R211C (on ENST00000405858 / NM_016265.4; = p.R173C on NM_006956.3) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs369502322, COSV61243669; called by muse, mutect2, varscan2
- ZNF438 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV59199716; called by muse, mutect2, varscan2
- ZNF462 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52948704; called by muse, mutect2, varscan2
- ZNF676 | c.1285G>A p.E429K (on ENST00000650058; = p.E397K on NM_001001411.3) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68093127, COSV68094587; called by muse, mutect2, varscan2
- ZNF683 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV62875482; called by muse, varscan2
- ZNF749 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV61947821; called by muse, mutect2, varscan2
- ZNF777 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 92/177 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.164); catalogued as rs774966698, COSV56099575; called by muse, mutect2, varscan2
- ZNF780B | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55467399; called by muse, mutect2, varscan2
- ZNF786 | c.1276T>A p.S426T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.412); catalogued as COSV60277478; called by muse, mutect2, varscan2
- ZNF79 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61071685; called by muse, mutect2, varscan2
- WDR46 | c.1205del p.H402Lfs*101 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, varscan2
- XAGE2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 79/136 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ABCA13 | c.10671C>T p.P3557= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV71293010; called by muse, mutect2
- ABCA7 | c.3762C>T p.L1254= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs769070739, COSV54029127; called by muse, mutect2, varscan2
- ABCC3 | c.3528T>C p.T1176= | Silent (SNP) | VAF 85/217 reads (39%) | catalogued as COSV53327551; called by muse, mutect2, varscan2
- ACKR2 | c.339G>A p.G113= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV56179551; called by muse, mutect2, varscan2
- ADAMTS13 | c.93C>T p.S31= | Silent (SNP) | VAF 44/70 reads (63%) | catalogued as COSV63022798; called by muse, mutect2, varscan2
- ADCY1 | c.2520C>T p.L840= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV52040758; called by muse, mutect2, varscan2
- AL121899.2 | c.1827C>T p.I609= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV67352096; called by muse, mutect2, varscan2
- ANK1 | c.21C>T p.F7= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV55892456; called by muse, mutect2, varscan2
- ANKRD52 | c.2346C>T p.P782= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs1486372326, COSV57286823; called by muse, mutect2, varscan2
- APOB | c.10254G>A p.T3418= | Silent (SNP) | VAF 239/760 reads (31%) | catalogued as rs781639766, COSV51928882; called by muse, mutect2, varscan2
- ARAP1 | c.2832T>C p.G944= (on ENST00000393609 / NM_001040118.2; = p.G699= on NM_015242.4) | Silent (SNP) | VAF 137/315 reads (43%) | catalogued as COSV61994157; called by muse, mutect2, varscan2
- ARGFX | c.690C>T p.I230= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as rs774717203, COSV57683491; called by muse, mutect2, varscan2
- ARL9 | c.715C>T p.L239= (on ENST00000640821 / NM_001363794.2; = p.L97= on NM_206919.2) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV63991479; called by muse, mutect2, varscan2
- ASNS | c.1341C>T p.L447= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV51555240; called by muse, mutect2, varscan2
- BTNL8 | c.93G>A p.L31= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV51460997; called by muse, mutect2
- C1orf109 | c.33G>A p.Q11= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV59240216; called by muse, mutect2, varscan2
- C7 | c.1308G>A p.V436= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100495432, COSV57470929, COSV57479187; called by muse, mutect2, varscan2
- CA10 | c.288G>A p.G96= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV53366917; called by muse, mutect2, varscan2
- CACNA1E | c.3015C>T p.P1005= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs373175706, COSV62413283; called by muse, mutect2, varscan2
- CALCB | c.324C>T p.F108= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs145827382; called by muse, mutect2, varscan2
- CCDC153 | c.414C>T p.D138= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as rs1378963923, COSV59541384; called by muse, mutect2, varscan2
- CCPG1 | c.1116G>A p.R372= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs753034527, COSV60527327; called by muse, mutect2, varscan2
- CD101 | c.2182C>T p.L728= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV56720443; called by muse, mutect2, varscan2
- CLCN5 | c.510C>T p.I170= | Silent (SNP) | VAF 36/52 reads (69%) | catalogued as rs868959055, COSV56586367; called by muse, mutect2, varscan2
- CNTD1 | c.165C>T p.I55= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55909096; called by muse, mutect2, varscan2
- COL11A1 | c.4344C>T p.S1448= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100615413, COSV62193825; called by muse, mutect2, varscan2
- COL13A1 | c.1617G>A p.G539= (on ENST00000398978 / NM_001130103.2; = p.G482= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV62573844; called by muse, mutect2, varscan2
- COQ5 | c.708G>T p.L236= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV56020194; called by muse, mutect2, varscan2
- COX18 | c.861C>T p.F287= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs762154229, COSV55721204; called by muse, mutect2, varscan2
- CUX1 | c.3489C>T p.D1163= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as COSV52911576; called by muse, mutect2, varscan2
- CYC1 | c.357G>A p.Q119= | Silent (SNP) | VAF 156/347 reads (45%) | catalogued as COSV100010196, COSV100010427; called by muse, mutect2, varscan2
- CYP4F3 | c.1011C>T p.L337= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs1386468090, COSV55412964; called by muse, mutect2, varscan2
- DCAF11 | c.447C>T p.S149= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV58110108; called by muse, varscan2
- DCX | c.1060C>T p.L354= (on ENST00000636035 / NM_001195553.2; = p.L348= on NM_000555.3) | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV57572789, COSV57574284; called by muse, mutect2, varscan2
- DMBT1 | c.6588C>T p.F2196= (on ENST00000338354 / NM_001377530.1; = p.F1439= on NM_004406.3) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs529670898, COSV57532770; called by muse, mutect2, varscan2
- DOCK2 | c.4065C>T p.F1355= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV56981570; called by muse, mutect2, varscan2
- EHHADH | c.1896C>T p.F632= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV51632694; called by muse, mutect2, varscan2
- ELMO3 | c.246C>T p.P82= (on ENST00000652269; = p.P29= on NM_024712.5) | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100681834, COSV62607501; called by muse, mutect2, varscan2
- ENTPD7 | c.420T>C p.T140= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV65113048; called by muse, mutect2, varscan2
- EPB41L1 | c.1395G>C p.R465= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52442997, COSV52445540; called by muse, mutect2, varscan2
- EPHA6 | c.2217C>T p.V739= (on ENST00000389672 / NM_001080448.3; = p.V131= on NM_173655.4) | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV67590273; called by muse, mutect2, varscan2
- ERICH3 | c.3036C>T p.S1012= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV58615463; called by muse, mutect2, varscan2
- EXPH5 | c.381C>T p.S127= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV56205992, COSV56207120; called by muse, mutect2, varscan2
- FBN3 | c.4146C>T p.P1382= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs760898849, COSV54469808; called by muse, mutect2, varscan2
- FCRL1 | c.741C>T p.I247= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs143378896, COSV63824412; called by muse, mutect2, varscan2
- FGFR2 | c.1143C>T p.Y381= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV60656556; called by muse, mutect2, varscan2
- FREM2 | c.3006G>A p.E1002= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as COSV54842868; called by muse, mutect2, varscan2
- GATA2 | c.1383C>T p.P461= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1200504281, COSV100350723, COSV62006276; called by muse, mutect2, varscan2
- GJB4 | c.423G>A p.V141= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV58356929; called by muse, mutect2, varscan2
- GSG1L | c.612C>T p.L204= (on ENST00000447459 / NM_001109763.2; = p.L49= on NM_144675.2) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs774836604, COSV66576791, COSV66579869; called by muse, mutect2, varscan2
- H1-6 | c.417G>A p.R139= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs763949700, COSV58091234; called by muse, mutect2, varscan2
- HAUS5 | c.429C>T p.L143= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52549438; called by muse, mutect2, varscan2
- HCN1 | c.2550C>T p.I850= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs772068771, COSV57532195; called by muse, mutect2, varscan2
- HECTD2 | c.1668T>C p.C556= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV53224214; called by muse, mutect2, varscan2
- HLA-G | c.111C>T p.S37= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV64406617; called by muse, mutect2, varscan2
- HRH2 | c.450C>T p.S150= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV51575797, COSV99199529; called by muse, mutect2, varscan2
- IFRD2 | c.1248C>T p.F416= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1312415934, COSV57115295; called by muse, mutect2, varscan2
- IKBIP | c.279C>T p.I93= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100141817; called by muse, mutect2, varscan2
- IMPG1 | c.1266G>A p.V422= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV64060925; called by muse, mutect2, varscan2
- ITGA11 | c.1260C>T p.N420= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV59881094; called by muse, mutect2, varscan2
- ITGB4 | c.3075C>T p.S1025= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV52331328; called by muse, mutect2
- KALRN | c.4146C>T p.S1382= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV53776751; called by muse, mutect2, varscan2
- KATNB1 | c.558T>G p.P186= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV65561652; called by muse, mutect2, varscan2
- KCNK1 | c.840C>T p.F280= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs866643709, COSV64035416, COSV64036100; called by muse, mutect2, varscan2
- KCNK10 | c.192G>A p.Q64= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV56641211, COSV56650843; called by muse, mutect2, varscan2
- KIR3DL3 | c.414G>A p.E138= | Silent (SNP) | VAF 67/249 reads (27%) | catalogued as COSV104391057, COSV99399939; called by muse, mutect2, varscan2
- LIMK2 | c.1902G>A p.R634= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs763018750, COSV53224373; called by muse, mutect2, varscan2
- LMTK3 | c.3498G>A p.P1166= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV54316289; called by muse, mutect2
- LRP1B | c.6141C>T p.I2047= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1393351438, COSV67262487; called by muse, mutect2, varscan2
- LRP1B | c.4839C>T p.F1613= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs766034085, COSV67188754, COSV67242118; called by muse, mutect2, varscan2
- LRRC37A3 | c.4117C>T p.L1373= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV58536868; called by muse, mutect2, varscan2
- MAP3K10 | c.1005C>T p.L335= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV53424710; called by muse, mutect2, varscan2
- METAP1D | c.216C>T p.D72= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV59931875; called by muse, mutect2, varscan2
- MFSD13A | c.807C>T p.F269= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs755557304, COSV53268844; called by muse, mutect2, varscan2
- MFSD4A | c.772C>T p.L258= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV65656876; called by muse, mutect2, varscan2
- MMP13 | c.969G>A p.T323= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs782597212, COSV52824858; called by muse, mutect2, varscan2
- MMP26 | c.121C>T p.L41= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56173729; called by muse, mutect2, varscan2
- MUC5AC | c.13923C>T p.F4641= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs77207494; called by muse, mutect2, varscan2
- MYO10 | c.2823C>T p.F941= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1339636355, COSV57028376; called by muse, mutect2, varscan2
- MYO10 | c.1200C>T p.S400= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV72563372; called by muse, mutect2, varscan2
- MYO15A | c.5871C>T p.S1957= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV52763470; called by muse, mutect2, varscan2
- MYOM3 | c.699G>A p.K233= | Silent (SNP) | VAF 106/329 reads (32%) | catalogued as COSV58399533; called by muse, mutect2, varscan2
- NALCN | c.4600C>T p.L1534= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV99215546; called by muse, mutect2, varscan2
- NALCN | c.4599C>T p.V1533= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV99215549; called by muse, mutect2, varscan2
- NMNAT3 | c.624C>T p.A208= (on ENST00000296202 / NM_001320512.1; = p.A171= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV56158813; called by muse, mutect2, varscan2
- NOS2 | c.795C>T p.I265= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV58226686; called by muse, mutect2, varscan2
- NPAP1 | c.2193G>A p.G731= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV61504975; called by muse, mutect2, varscan2
- NRG2 | c.1011C>T p.S337= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV56838899; called by muse, mutect2, varscan2
- NUP85 | c.498C>T p.L166= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV55466197; called by muse, mutect2, varscan2
- OR10H4 | c.594C>T p.I198= | Silent (SNP) | VAF 91/247 reads (37%) | catalogued as rs1478959229, COSV59062722; called by muse, mutect2, varscan2
- OR10K1 | c.885G>A p.K295= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV56873591; called by muse, mutect2, varscan2
- OR1M1 | c.588G>A p.R196= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV70037427; called by muse, mutect2, varscan2
- OR6C70 | c.142C>T p.L48= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV59245166, COSV59245316; called by muse, mutect2, varscan2
- PALD1 | c.1350C>T p.F450= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs1426828775, COSV54970916, COSV54977257; called by muse, mutect2, varscan2
- PAX3 | c.192C>T p.H64= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1559320466, COSV99286618; called by muse, mutect2, varscan2
- PCDHGB2 | c.1725C>T p.F575= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV53905143; called by muse, mutect2, varscan2
- PCP4 | c.159C>T p.F53= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs761973180, COSV60786943, COSV60788644; called by muse, mutect2, varscan2
- PGLS | c.537G>A p.P179= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs748786428, COSV53115237; called by muse, mutect2
- PHLPP2 | c.1461C>T p.A487= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV62426845; called by muse, mutect2, varscan2
- PIK3R5 | c.2475G>A p.K825= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV52657652; called by muse, mutect2, varscan2
- PLA2R1 | c.1971G>A p.E657= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV51785107; called by muse, mutect2, varscan2
- PLCL2 | c.2211C>T p.V737= (on ENST00000615277 / NM_001144382.2; = p.V611= on NM_015184.5) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV67624570; called by muse, mutect2, varscan2
- PM20D1 | c.1128C>T p.L376= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV65649487; called by muse, mutect2, varscan2
- POLR3K | c.138G>A p.L46= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV53453441; called by muse, mutect2, varscan2
- POTEF | c.2428C>T p.L810= | Silent (SNP) | VAF 66/209 reads (32%) | catalogued as COSV62543597; called by muse, varscan2
- POTEH | c.585C>T p.I195= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs778514449, COSV100624994; called by muse, mutect2, varscan2
- PPIP5K2 | c.3720G>A p.G1240= (on ENST00000358359 / NM_001276277.3; = p.G1219= on NM_015216.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV58608818; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1530C>T p.V510= (on ENST00000352766; = p.V431= on NM_181334.5) | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs1177682823, COSV61236158; called by muse, mutect2, varscan2
- PSMC3 | c.399C>T p.F133= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV54082347; called by muse, mutect2, varscan2
- PTPRF | c.5595C>T p.V1865= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs753391620, COSV63448027; called by muse, mutect2, varscan2
- PTTG2 | c.261C>T p.S87= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs541513996, COSV54725492; called by muse, mutect2, varscan2
- PTX4 | c.381C>T p.L127= (on ENST00000447419 / NM_001328608.2; = p.L122= on NM_001013658.1) | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs1178103859, COSV53519048; called by muse, mutect2, varscan2
- RABL6 | c.1542G>A p.R514= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs776147014, COSV100273395; called by muse, mutect2
- RBM42 | c.534C>T p.A178= | Silent (SNP) | VAF 41/190 reads (22%) | catalogued as rs1034844747, COSV99387051; called by muse, mutect2, varscan2
- RHOH | c.483G>A p.Q161= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV101110516; called by muse, mutect2, varscan2
- RMND5B | c.414G>A p.E138= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57745864; called by muse, mutect2, varscan2
- SH2D3A | c.657C>T p.F219= | Silent (SNP) | VAF 95/347 reads (27%) | catalogued as COSV55587521, COSV55588199; called by muse, mutect2, varscan2
- SHKBP1 | c.1623C>T p.P541= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs550402674, COSV52540045; called by muse, mutect2
- SIGLEC14 | c.888C>T p.S296= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV55782826; called by muse, mutect2, varscan2
- SIRT6 | c.870C>T p.P290= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs780247842, COSV50253636; called by muse, mutect2, varscan2
- SLC13A2 | c.1449C>T p.F483= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV58995932; called by muse, mutect2, varscan2
- SLC16A14 | c.537G>A p.L179= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV54620823; called by muse, mutect2, varscan2
- SLC18A1 | c.1359G>A p.K453= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52350751; called by muse, mutect2, varscan2
- SLC2A2 | c.1551C>T p.F517= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV100049046, COSV58588130; called by muse, mutect2, varscan2
- SLC30A8 | c.519C>T p.I173= | Silent (SNP) | VAF 179/806 reads (22%) | catalogued as COSV69974674; called by muse, mutect2, varscan2
- SNAPC4 | c.3600C>T p.P1200= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1452967613, COSV53736640; called by muse, mutect2, varscan2
- SPECC1 | c.258G>A p.T86= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs201890028, COSV54956855; called by muse, mutect2, varscan2
- TAOK2 | c.3237G>A p.R1079= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV99663093; called by muse, mutect2, varscan2
- TENM1 | c.1914C>T p.I638= | Silent (SNP) | VAF 99/170 reads (58%) | catalogued as COSV64440501; called by muse, mutect2, varscan2
- TENM2 | c.3045C>T p.S1015= (on ENST00000518659 / NM_001122679.2; = p.S783= on NM_001080428.3) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV69123642; called by muse, mutect2, varscan2
- TENT2 | c.1167C>T p.D389= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as COSV99706569; called by muse, mutect2, varscan2
- TET3 | c.3684C>T p.S1228= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1000525898, COSV69645062; called by muse, mutect2, varscan2
- TMEM131 | c.5400C>T p.S1800= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV51783999; called by muse, mutect2, varscan2
- TMEM89 | c.366C>T p.L122= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs868602873, COSV56570281; called by muse, mutect2, varscan2
- TNK1 | c.1782G>A p.K594= (on ENST00000576812 / NM_001251902.2; = p.K589= on NM_003985.5) | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV61172043; called by muse, mutect2, varscan2
- TRAJ48 | c.36G>A p.G12= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- TRAV8-2 | c.276C>T p.S92= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs764752764; called by muse, mutect2, varscan2
- TRIM28 | c.1128C>T p.L376= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV53400534, COSV53401542; called by muse, mutect2, varscan2
- TRMT5 | c.55C>T p.L19= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV50785118; called by muse, mutect2, varscan2
- TSC2 | c.4092C>T p.S1364= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs1251019267, COSV51923495; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSPAN18 | c.132C>T p.I44= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs747032387, COSV60884140; called by muse, mutect2, varscan2
- TTC17 | c.3240C>T p.I1080= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as rs1328823663, COSV50010390; called by muse, mutect2, varscan2
- TTN | c.93723G>A p.L31241= (on ENST00000591111; = p.L23817= on NM_003319.4) | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV60279186; called by muse, mutect2, varscan2
- TTN | c.29268C>T p.I9756= (on ENST00000591111; = p.I8829= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs369709449, COSV59976609; called by muse, mutect2
- TUBA1B | c.1236G>A p.G412= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as COSV60138009; called by muse, mutect2, varscan2
- UTP25 | c.1893C>T p.F631= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV71966123; called by muse, mutect2, varscan2
- VAC14 | c.1464C>T p.L488= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV55756816; called by muse, mutect2, varscan2
- WDR31 | c.345C>T p.S115= (on ENST00000374193 / NM_001006615.3; = p.S114= on NM_145241.5) | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV59145542; called by muse, mutect2, varscan2
- WNT5B | c.462G>A p.R154= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs752905902, COSV60198784; called by muse, mutect2, varscan2
- ZFHX3 | c.2133C>T p.P711= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV99212998; called by muse, mutect2, varscan2
- ZIK1 | c.522G>A p.K174= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV56738244; called by muse, mutect2, varscan2
- ZNF670 | c.714T>C p.S238= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV63608804; called by muse, mutect2, varscan2
- ZNF672 | c.1107C>T p.C369= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1184160542, COSV60638869; called by muse, mutect2, varscan2
- ZNF99 | c.1020C>T p.P340= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs878889031, COSV68056452; called by muse, mutect2, varscan2
- ACSL5 | c.-78G>A | 5'UTR (SNP) | VAF 36/127 reads (28%) | catalogued as COSV61132934; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826647 C>T | 3'Flank (SNP) | VAF 59/101 reads (58%) | called by muse, mutect2, varscan2
- CYP4F3 | c.*1G>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs1385190278, COSV99658243; called by muse, mutect2, varscan2
- IGHV1-12 | n.188G>A | RNA (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- KCNIP2 | c.73+3726C>T | Intron (SNP) | VAF 52/165 reads (32%) | catalogued as COSV99493414; called by muse, mutect2, varscan2
- KIF1B | c.2115+7244A>G | Intron (SNP) | VAF 50/78 reads (64%) | catalogued as COSV99823470, COSV99823476; called by muse, mutect2, varscan2
- MIR563 | n.68C>T | RNA (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- MRPS17P9 | n.35G>A | RNA (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- SNORD113-6 | n.31G>A | RNA (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- SSPOP | n.15459G>A | RNA (SNP) | VAF 14/32 reads (44%) | catalogued as COSV65135508; called by muse, mutect2, varscan2
